Gene-level copy-number profile of tumor specimen TCGA-85-8070-01A from TCGA case TCGA-85-8070, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 71.7 years (26,183 days).
Specimen TCGA-85-8070-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.273c54f0-e5f0-4684-a1df-82a79554637d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8070-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6e173d01-c6c7-4285-8148-f51032233ef1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 34; copy number 2: 18,153; copy number 3: 13,299; copy number 4: 17,851; copy number 5: 4,154; copy number 6: 2,716; copy number 7: 2,470; copy number 8: 611; copy number 9: 164; copy number 10: 24; copy number 11: 1; copy number 14: 122; copy number 16: 37; copy number 17: 123; copy number 18: 8; copy number 23: 3; copy number 24: 27; copy number 26: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8070-01A-11D-2243-01): tumor purity 0.95, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 521 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:21,812,265–23,194,729, 45 genes, copy number 17–24: LDLRAD2, HSPG2, AL590556.1, AL590556.2, CELA3B, AL590556.3, RN7SL386P, RNU6-1022P, CELA3A, RN7SL186P, RNU6-776P, LINC01635, LINC00339, CDC42, CDC42-AS1, AL031281.1, CDC42-IT1, MPHOSPH6P1, WNT4, AL445253.1, MIR4418, PPIAP34, AL591122.1, ZBTB40, ZBTB40-IT1, EPHA8, MIR6127, C1QA, C1QC, C1QB, EPHB2, MIR4684, AL512444.1, MIR4253, LACTBL1, TEX46, KDM1A, AL031428.1, MIR3115, AL031428.2, LUZP1, AL161672.1, RNU6-514P, RNU6-135P, HTR1D.
- chr1:25,800,176–26,171,831, 26 genes, copy number 17: SELENON, AL020996.2, AL020996.1, MTFR1L, AL020996.3, AUNIP, AL033528.2, PAQR7, Y_RNA, STMN1, SNRPFP2, AL033528.1, MIR3917, PAFAH2, RNU6-110P, AL592064.1, AL592064.2, EXTL1, SLC30A2, AL391650.2, TRIM63, PDIK1L, FAM110D, C1orf232, AL391650.1, ZNF593.
- chr2:47,345,158–63,197,037, 224 genes, copy number 14–26 (within-gene range 4–26) (broad region; genes not listed).
- chr2:63,168,600–63,233,577, 2 genes, copy number 26: Metazoa_SRP, MTFR2P1.
- chr3:164,670,878–174,378,005, 137 genes, copy number 9 (broad region; genes not listed).
- chr3:174,631,823–174,632,064, 1 gene, copy number 9: RN7SKP40.
- chr8:35,862,123–38,382,272, 62 genes, copy number 9–14 (within-gene range 6–14) (broad region; genes not listed).
- chr19:22,286,441–22,667,671, 24 genes, copy number 10: ZNF729, BNIP3P31, AC011494.1, RPL34P34, ZNF98, AC011516.1, BNIP3P32, AC025811.1, BNIP3P33, ZNF209P, AC004004.1, AC011467.6, AC011467.1, LINC01233, RNU6-1179P, AC011467.5, GOLGA2P9, RN7SL860P, AC011467.3, AC011467.4, RAD54L2P1, LINC01785, AC011467.2, ZNF492.

Autosomal genes at a single copy (total copy number 1): 34. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
